EXCEPTIONAL_RESPONDERS case ER-AD8S — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/25af3eac-7fb8-4b25-9fa8-2a40d30768d5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1935; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 76.6 years (27,991 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC clinical stage: Stage IV; Prior malignancy: no; Days to last follow up: 1,219 days (3.3 years); Days to best overall response: 564 days (1.5 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Fluorouracil; Days to treatment start: 28 days; Days to treatment end: 63 days.
   Treatment given: Therapeutic agents: Leucovorin Calcium + Oxaliplatin; Days to treatment start: 28 days; Days to treatment end: 189 days.

Follow-up (1 entry)
- Days to follow up: 1,219 days (3.3 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 19 days; Days progression-free: 1,219 days (3.3 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AD8S-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample ER-AD8S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AD8S-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 5; Percent tumor nuclei: 5; Percent normal cells: 50; Percent necrosis: 35; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
